CPTAC case C3L-03622 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/be818f7f-c64f-43d8-9285-37d3ce16a1b1

Demographics
Sex at birth: female; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Head of pancreas; Site of resection or biopsy: Head of pancreas; Age at diagnosis: 72.5 years (26,464 days); AJCC staging edition: 7th; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Last known disease status: Tumor free; Days to last known disease status: 339 days; Progression or recurrence: no; Days to last follow up: 339 days.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 2017; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples)
- Sample C3L-03622-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 84 mg.
- Sample C3L-03622-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Preservation method: Frozen.
